Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5175, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5175-01A (Primary Tumor).

[page 1 of 2]
Med. Rec. #:

DOB:

Gender:

Ref. Physician:

Patient Address:

Ref. Source:

Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Clinical Diagnosis & History:

with right renal mass.

TCGA - BP - 5175

Specimens Submitted:

1: SP:Kidney, right; partial nephrectomy

2: SP:Kidney, deep margin #2, excision

3: SP:Kidney, right, excision

DIAGNOSIS:

1. SP:Kidney, right; partial nephrectomy

- RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR CELL TYPE), NUCLEAR GRADE III/IV.
- THE PATTERN OF GROWTH IS ACINAR.
- THE TUMOR GREATEST DIAMETER IS 2.8 CM. ✓
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE. ✓
- NO INVASION OF THE RENAL VEIN IS IDENTIFIED.
- SURGICAL MARGIN IS FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. ✓

2. SP:Kidney, deep margin #2, excision

BENIGN RENAL PARENCHYMA.

3. SP:Kidney, right, excision

BENIGN RENAL PARENCHYMA.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1) The specimen is received fresh for frozen section consultation labeled, "Right renal tumor-stitch marks deep margin #1", and consists of a 4.5 x 4 x 2.5 cm resected portion of kidney parenchyma. There is a stitch marking the deep margin. The deep margin is inked black. Cut-section shows a 2.8 x 2.5 x 2.5 cm well-encapsulated yellow-orange tumor mass with hemorrhagic and necrotic areas. The tumor is grossly 0.3 cm from the deep margin. A representative section is frozen. A sample is given to TPS. Representative sections are submitted.

Summary of sections:

FSC-frozen section control

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

TM-tumor with deep margin
T-tumor

2) The specimen is received fresh for frozen section consultation labeled, "Deep margin #2", and consists of a piece of yellow-tan soft tissue measuring 2 x 1.3 x 0.3 cm, which is entirely frozen.

Summary of sections:
FSC-frozen section control

3) The specimen is received in formalin, labeled, "Right renal tissue". It consists of a 4.0 x 1.5 x 0.6 cm triangular renal tissue with outer capsule and irregular opposite surface. The capsular surface is inked black and representative sections are submitted.

Summary of Sections:
RS – representative sections

Summary of Sections:

Part 1: SP:Kidney, right; partial nephrectomy (tl)

Block	Sect. Site	PCs
1	fsc	1
2	t	2
2	tm	2

Part 2: SP:Kidney, deep margin #2, excision

Block	Sect. Site	PCs
1	fsc	1

Part 3: SP:Kidney, right, excision (tl)

Block	Sect. Site	PCs
4	rs	4

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: RENAL CORTICAL EPITHELIAL TUMOR. MARGINS BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN
PERMANENT DIAGNOSIS: SAME.

Source: NCI Genomic Data Commons file b58bbf82-6442-4035-96f1-d0ee14af7393 (TCGA-BP-5175.1F0940EE-175F-4ADF-AA46-3F6B240E3A2E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).